Somatic mutation profile of tumor specimen TCGA-49-AAR4-01A (aliquot TCGA-49-AAR4-01A-12D-A410-08) from TCGA case TCGA-49-AAR4, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 51.9 years (18,939 days).
Specimen TCGA-49-AAR4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 963ab360-a6c6-4ceb-8546-be217ff8be35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-AAR4-11A (Solid Tissue Normal), aliquot TCGA-49-AAR4-11A-11D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9b5f716-ee0e-46d6-a4ca-e2b9003a436a

The open-access MAF lists 587 somatic variants for this specimen: 454 protein-altering or splice-affecting, 115 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 395, Silent 115, Nonsense Mutation 26, Splice Site 15, Frame Shift Del 12, RNA 6, Translation Start Site 5, Intron 5, 3'UTR 3, 5'Flank 2, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIT1 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs869025191, CM149836, CM161971, CM161972, COSV64170884, COSV64171290, COSV64171744; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- ABCA10 | c.2936G>T p.G979V | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99289162; called by muse, mutect2, varscan2
- ABCA12 | c.6950G>T p.R2317I (on ENST00000272895 / NM_173076.3; = p.R1999I on NM_015657.3) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99791468; called by muse, mutect2
- ABCB11 | c.2244T>A p.S748R | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV99792728; called by muse, mutect2, varscan2
- ABCC8 | c.1005G>T p.Q335H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.482); catalogued as rs1377546646, COSV100217608; called by muse, mutect2, varscan2
- ABCC9 | c.4582G>A p.D1528N | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99685278, COSV99686719; called by muse, mutect2
- ABI3BP | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99428175; called by muse, mutect2, varscan2
- ACOT11 | c.1347G>T p.R449S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100156956, COSV100157067; called by muse, mutect2
- ACSM2B | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100313036; called by muse, mutect2, varscan2
- ACTN2 | c.1852G>T p.V618L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV100856923, COSV63974201; called by muse, mutect2, varscan2
- ACTR1A | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100883729; called by muse, mutect2
- ADAMTS12 | c.4193G>T p.R1398L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV100711534, COSV61260153; called by muse, mutect2, varscan2
- ADAMTS14 | c.2570C>A p.A857D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs754735629, COSV64601392, COSV64604949; called by muse, mutect2, varscan2
- ADCY10 | c.963C>G p.I321M | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309213770, COSV100897021; called by muse, mutect2
- ADCY8 | c.1111-2A>T p.X371_splice | Splice Site (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99653692; called by muse, mutect2
- ADGRB1 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 13/101 reads (13%) | catalogued as COSV100030179, COSV60095791; called by muse, mutect2, varscan2
- ADGRL2 | c.2291G>T p.R764L (on ENST00000370717 / NM_001366005.1; = p.R751L on NM_012302.4) | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54684346, COSV54684938; called by muse, mutect2, varscan2
- ADGRL2 | c.3832A>T p.T1278S (on ENST00000370717 / NM_001366005.1; = p.T1222S on NM_012302.4) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.001); catalogued as COSV99590827; called by muse, mutect2
- AFF2 | c.3586G>C p.V1196L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV53994071, COSV99665645; called by muse, mutect2
- AGT | c.1441C>A p.P481T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794465; called by muse, mutect2, varscan2
- AHSG | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV99890260; called by muse, mutect2, varscan2
- ANKRD30A | c.3677C>A p.A1226E (on ENST00000611781; = p.A1170E on NM_052997.2) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs779261333, COSV100654224, COSV100654428; called by muse, mutect2, varscan2
- ANO4 | c.2694A>G p.I898M (on ENST00000392977 / NM_001286615.2; = p.I863M on NM_178826.4) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100153520; called by muse, mutect2
- APOA1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99369349; called by muse, mutect2, varscan2
- APOB | c.3004G>T p.E1002* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99267223; called by muse, mutect2
- ARAP3 | c.2107+1G>T p.X703_splice | Splice Site (SNP) | VAF 16/78 reads (21%) | catalogued as rs1459202017, COSV99500138; called by muse, mutect2, varscan2
- ARFGEF3 | c.2428G>A p.D810N | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as rs1364884608, COSV99294434; called by muse, mutect2
- ARHGAP11A | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100853330; called by muse, mutect2
- ARHGAP20 | c.1684G>T p.V562F | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.091); catalogued as rs1342803715, COSV99504973; called by muse, mutect2
- ARHGAP5 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV61538182, COSV61538725; called by muse, mutect2, varscan2
- ARHGEF6 | c.2086C>G p.L696V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99166633; called by muse, mutect2, varscan2
- ARL4A | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV100775954; called by muse, mutect2
- ASPM | c.4592G>T p.R1531L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs200681905, COSV54139741, COSV99660913; called by muse, mutect2, varscan2
- ATOH1 | c.736G>T p.G246W | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1375070120, COSV60038016; called by muse, mutect2
- ATRNL1 | c.2165G>T p.C722F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100746726; called by muse, mutect2, varscan2
- BAZ1B | c.1936G>T p.G646C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV100290021; called by muse, mutect2, varscan2
- BAZ2B | c.4808G>C p.G1603A | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.011); catalogued as COSV100600889; called by muse, mutect2, varscan2
- BNC1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV61757116, COSV61758705; called by muse, mutect2
- BRIP1 | c.2124G>C p.W708C | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99370760; called by muse, mutect2, varscan2
- BRS3 | c.304C>G p.P102A | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101036640, COSV65711339; called by muse, mutect2, varscan2
- BTNL9 | c.478T>A p.S160T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV100576216; called by muse, mutect2
- C10orf88 | c.1099G>T p.V367F | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100925039; called by muse, mutect2
- C4orf17 | c.819A>T p.E273D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.107); catalogued as COSV100431070; called by muse, mutect2
- CALHM1 | c.408C>A p.S136R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs554951738, COSV100324369, COSV100324384; called by muse, mutect2
- CAMK4 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV100000050; called by muse, mutect2
- CAMK4 | c.162-1G>T p.X54_splice | Splice Site (SNP) | VAF 13/114 reads (11%) | catalogued as COSV100000051; called by muse, mutect2, varscan2
- CAPN11 | c.1211C>A p.S404Y | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV101291933; called by muse, mutect2
- CATSPER1 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV100376181; called by muse, mutect2, varscan2
- CCDC88B | c.213del p.S72Afs*23 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | catalogued as rs1415406811, COSV57266194; called by mutect2, pindel, varscan2
- CCKAR | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.21); catalogued as COSV99810470; called by muse, mutect2
- CCR5 | c.1030G>A p.G344R | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV99433602; called by muse, mutect2, varscan2
- CCT8L2 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100743008; called by muse, mutect2, varscan2
- CDC42 | c.37G>C p.A13P | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100212661; called by muse, mutect2
- CDCP1 | c.1130G>C p.C377S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV99944241; called by muse, mutect2, varscan2
- CDH11 | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV51757218; called by muse, mutect2
- CDON | c.800A>T p.N267I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as rs766151030, COSV99701816; called by mutect2, varscan2
- CEP192 | c.5415A>T p.R1805S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as COSV100381872; called by muse, mutect2, varscan2
- CHD4 | c.1685A>T p.Q562L (on ENST00000357008 / NM_001363606.2; = p.Q575L on NM_001273.5) | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.954); catalogued as COSV100538838; called by muse, mutect2
- CHD9 | c.4012G>C p.E1338Q | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV99529576; called by muse, mutect2
- CHL1 | c.1652C>A p.S551Y (on ENST00000397491 / NM_001253387.1; = p.S567Y on NM_006614.4) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV99852007; called by muse, mutect2
- CHST1 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100346454; called by muse, mutect2
- CNGB3 | c.542C>A p.T181K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100182777; called by muse, mutect2, varscan2
- COG2 | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV100794773, COSV64187731; called by muse, mutect2
- COL1A1 | c.3990G>C p.M1330I | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.888); catalogued as COSV99867915; called by muse, mutect2
- COL5A2 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396123186, COSV100880664, COSV66407040; called by muse, mutect2, varscan2
- CPS1 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99243809; called by muse, mutect2, varscan2
- CPXCR1 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV52161558, COSV99342366; called by muse, mutect2, varscan2
- CRTAM | c.163G>T p.G55W | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99912215; called by muse, mutect2
- CRYGN | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100484797; called by muse, mutect2
- CSE1L | c.2612C>G p.S871C | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV53705162; called by muse, mutect2
- CSF2RB | c.670G>T p.G224* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as COSV99454290; called by muse, mutect2
- CSMD3 | c.5563G>C p.V1855L (on ENST00000297405 / NM_001363185.1; = p.V1751L on NM_052900.3) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV99843809; called by muse, mutect2, varscan2
- CSMD3 | c.3349C>A p.H1117N (on ENST00000297405 / NM_001363185.1; = p.H1013N on NM_052900.3) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.3); catalogued as COSV99820500, COSV99843814; called by muse, mutect2, varscan2
- CSTF2 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100880849; called by muse, mutect2, varscan2
- CUL7 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV54812855, COSV99539106; called by muse, mutect2
- CWH43 | c.1387A>G p.T463A | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.352); catalogued as COSV99893837; called by muse, mutect2
- CYP1A1 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101122371; called by muse, mutect2, varscan2
- CYP2C18 | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99608824; called by muse, mutect2
- DCAF4L2 | c.273A>T p.Q91H | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100151192; called by muse, mutect2, varscan2
- DCTN1 | c.3196G>T p.E1066* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100721033; called by muse, mutect2
- DDX46 | c.2309G>T p.S770I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV100844914; called by muse, mutect2, varscan2
- DENND1A | c.1628A>G p.E543G | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV101012225; called by muse, mutect2, varscan2
- DHTKD1 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV53803008; called by muse, mutect2, varscan2
- DLGAP3 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs550993893, COSV52394000; called by muse, mutect2, varscan2
- DMXL2 | c.4655G>T p.R1552I | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as COSV99198046; called by muse, mutect2, varscan2
- DNAH3 | c.8151G>C p.M2717I | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs1321947638, COSV99769737; called by muse, mutect2
- DNAH9 | c.6185C>A p.P2062H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as rs1454666268, COSV52373837, COSV99307425; called by muse, mutect2, varscan2
- DNM3 | c.1278G>T p.K426N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100798573, COSV62469868; called by muse, mutect2, varscan2
- DOCK7 | c.5848G>C p.D1950H (on ENST00000635253 / NM_001367561.1; = p.D1919H on NM_033407.3) | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99225574; called by muse, mutect2
- DPP10 | c.1369A>T p.T457S | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); catalogued as COSV100070439; called by muse, mutect2, varscan2
- DPP10 | c.2300A>G p.Y767C | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as rs1260933187, COSV100070441; called by muse, mutect2, varscan2
- DPP9 | c.373G>T p.E125* (on ENST00000598800; = p.E154* on NM_139159.5) | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99506416; called by muse, mutect2, varscan2
- DPRX | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV100934114; called by muse, mutect2, varscan2
- DQX1 | c.848G>A p.R283K | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1374094004; called by muse, mutect2
- DSCAML1 | c.4769C>A p.A1590D (on ENST00000321322; = p.A1530D on NM_020693.4) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV100356847; called by muse, mutect2
- DSG3 | c.2692T>A p.C898S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs771980752, COSV57129099, COSV99934587; called by muse, mutect2, varscan2
- DTNBP1 | c.142G>T p.G48* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as COSV100161054; called by muse, mutect2
- DUSP10 | c.1196A>T p.Q399L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as COSV100100712; called by muse, mutect2, varscan2
- DUSP5 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100851931; called by muse, mutect2
- DZIP1L | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV100551620; called by muse, mutect2, varscan2
- EGF | c.810G>C p.W270C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.784); catalogued as COSV54479577, COSV99491265; called by muse, mutect2, varscan2
- EIF3E | c.669C>A p.F223L | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99622899; called by muse, mutect2
- ELMO1 | c.1733G>T p.R578L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1274388140, COSV100165599; called by muse, mutect2, varscan2
- ENPP2 | c.867A>G p.I289M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.175); catalogued as COSV99309105; called by muse, mutect2, varscan2
- EPB41L2 | c.2556G>C p.E852D | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV100441238; called by muse, mutect2, varscan2
- EPB41L3 | c.2329G>T p.E777* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV59443662, COSV59470752; called by muse, mutect2, varscan2
- ESPL1 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99229636; called by muse, mutect2
- EYA2 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.616); catalogued as COSV100427183; called by mutect2, varscan2
- FAAH | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.741); catalogued as COSV99680206; called by muse, mutect2, varscan2
- FABP1 | c.334-1G>T p.X112_splice | Splice Site (SNP) | VAF 11/112 reads (10%) | catalogued as rs112023736, COSV99860951; called by muse, mutect2, varscan2
- FAM104A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV99721737; called by muse, mutect2, varscan2
- FAM184A | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV58852760; called by muse, mutect2
- FAM47A | c.1906A>T p.R636* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100650016; called by muse, mutect2, varscan2
- FAM47C | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100792884; called by muse, mutect2, varscan2
- FAM47C | c.1224G>T p.K408N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.647); catalogued as COSV100792886; called by muse, mutect2, varscan2
- FAM50B | c.558G>C p.E186D | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.072); catalogued as COSV100976596; called by muse, mutect2
- FASTKD2 | c.500G>T p.S167I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99379174; called by muse, mutect2, varscan2
- FAT1 | c.4040C>G p.S1347C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs1318017548, COSV101499576; called by muse, mutect2
- FBN3 | c.2233G>T p.G745C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99561568; called by muse, mutect2, varscan2
- FEZF2 | c.1158G>T p.E386D | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV99334926; called by muse, mutect2
- FLG | c.7013C>A p.A2338E | Missense Mutation (SNP) | VAF 41/508 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.587); catalogued as rs1368504513, COSV64251494; called by muse, mutect2
- FLG | c.2973C>A p.D991E | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.286); catalogued as COSV100911962; called by muse, mutect2
- FLRT3 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs1196290800, COSV99440216; called by muse, mutect2
- FSTL5 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100059628; called by muse, mutect2, varscan2
- FSTL5 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100055492, COSV100059631; called by muse, mutect2
- GABRA3 | c.26G>T p.C9F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV64802211; called by muse, mutect2, varscan2
- GBP4 | c.1628C>A p.A543D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.049); catalogued as COSV100864443; called by muse, mutect2, varscan2
- GLI2 | c.3148G>T p.V1050L (on ENST00000361492 / NM_001374353.1; = p.V1067L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.112); catalogued as COSV100084048; called by muse, mutect2, varscan2
- GMPS | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99903324; called by muse, mutect2
- GPR141 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.295); catalogued as COSV100550406; called by muse, varscan2
- GRAMD1B | c.830T>G p.L277R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.467); catalogued as COSV100455090; called by muse, mutect2, varscan2
- GRID2 | c.2735C>A p.T912K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV99945057; called by muse, mutect2, varscan2
- GRIN2B | c.2777G>A p.R926Q | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as rs1340550286, COSV101663145; called by muse, mutect2
- GRIN3A | c.1974G>T p.R658S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100701714; called by muse, mutect2
- GRIN3A | c.1973G>T p.R658M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100701715; called by muse, mutect2
- GRIP1 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.157); catalogued as COSV99670531; called by muse, mutect2
- HAS2 | c.1104G>T p.W368C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100392096; called by muse, mutect2
- HEATR1 | c.4392G>A p.M1464I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100857761; called by muse, mutect2, varscan2
- HECW1 | c.2326C>A p.P776T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV101224158; called by mutect2, varscan2
- HECW1 | c.2942C>G p.T981S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV101224159; called by muse, mutect2, varscan2
- HHIP | c.1645G>A p.G549S | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs201603291, COSV99667686; called by muse, mutect2, varscan2
- HIVEP1 | c.8087G>T p.R2696M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101045593; called by muse, mutect2, varscan2
- HLA-G | c.597del p.K200Rfs*14 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as COSV104421731; called by mutect2, pindel, varscan2
- HMCN1 | c.6217G>T p.A2073S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99634010; called by muse, mutect2
- HMCN1 | c.12499+1G>C p.X4167_splice | Splice Site (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99634012; called by muse, mutect2, varscan2
- HMCN1 | c.13040-1G>T p.X4347_splice | Splice Site (SNP) | VAF 7/54 reads (13%) | catalogued as COSV99634015; called by muse, mutect2
- HRAS | c.157T>A p.L53M | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99530670; called by muse, mutect2
- HTR1F | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100138218; called by muse, mutect2, varscan2
- HTR2C | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as COSV99350507; called by muse, mutect2
- HUWE1 | c.8708G>A p.R2903K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.001); catalogued as COSV53343506, COSV99473766; called by muse, mutect2, varscan2
- IGLL3P | n.118T>C | Splice Region (SNP) | VAF 4/42 reads (10%) | catalogued as rs1314174422; called by muse, mutect2
- IGLV6-57 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs1478197661, COSV101135317; called by muse, mutect2, varscan2
- IKZF2 | c.813del p.N272Ifs*30 | Frame Shift Del (DEL) | VAF 8/83 reads (10%) | catalogued as COSV59585651; called by mutect2, pindel, varscan2
- IL1A | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.114); catalogued as COSV99641474; called by muse, mutect2, varscan2
- INSRR | c.3127-2A>T p.X1043_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100947937; called by muse, mutect2, varscan2
- INSYN1 | c.165C>A p.S55R | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.759); catalogued as COSV101138822; called by muse, mutect2
- IQGAP1 | c.1282C>T p.L428F | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV99185283; called by muse, mutect2
- IQGAP2 | c.2308T>A p.Y770N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99167852; called by muse, mutect2, varscan2
- ITFG2 | c.1155G>T p.Q385H | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV99958280; called by muse, mutect2
- ITGA6 | c.1114A>G p.I372V (on ENST00000442250; = p.I333V on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99905908; called by muse, mutect2
- ITPR3 | c.6479A>G p.E2160G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100967919; called by mutect2, varscan2
- ITPRID1 | c.1936C>A p.H646N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.215); catalogued as COSV100087226; called by muse, mutect2, varscan2
- IVL | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100908238; called by muse, mutect2, varscan2
- IVL | c.155C>A p.P52Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV100908240; called by muse, mutect2, varscan2
- JAM3 | c.171T>A p.D57E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.525); catalogued as COSV100138402; called by muse, mutect2, varscan2
- KAT7 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs555218442, COSV99372014; called by muse, mutect2, varscan2
- KCND2 | c.574G>T p.G192W | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100477864; called by muse, mutect2
- KCTD3 | c.1899G>T p.Q633H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV99379612; called by muse, mutect2, varscan2
- KIAA1549 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV54305351, COSV99651675; called by mutect2, varscan2
- KIF18B | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399875624, COSV100192483; called by muse, mutect2
- KIF1A | c.2656G>A p.A886T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100241993; called by muse, mutect2
- KIF2B | c.476A>T p.Q159L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV99275965; called by muse, mutect2, varscan2
- KLHL41 | c.400A>T p.N134Y | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99500557; called by muse, mutect2
- KMT2A | c.1385C>G p.S462* | Nonsense Mutation (SNP) | VAF 8/142 reads (6%) | catalogued as COSV100629538; called by muse, mutect2
- KRT37 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs1555556005, COSV56657844, COSV99845661; called by muse, mutect2, varscan2
- KRTAP10-10 | c.433G>C p.A145P | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.522); catalogued as rs1555937389, COSV100555000; called by muse, mutect2, varscan2
- KRTAP10-12 | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100555002; called by muse, mutect2, varscan2
- L1CAM | c.2272G>T p.G758W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100649415; called by muse, mutect2, varscan2
- LAMA1 | c.2909A>T p.H970L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV101057369; called by muse, mutect2
- LAMA2 | c.2626C>A p.P876T | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs773724438, COSV101370746; called by muse, mutect2, varscan2
- LAMA4 | c.1237C>T p.P413S (on ENST00000230538 / NM_001105206.3; = p.P406S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV100039133; called by muse, mutect2, varscan2
- LANCL2 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99635045; called by muse, mutect2, varscan2
- LARGE1 | c.788-2A>T p.X263_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100506147; called by muse, mutect2, varscan2
- LGALS3 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99582504; called by muse, mutect2, varscan2
- LIMCH1 | c.452A>T p.K151M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100574260; called by muse, mutect2, varscan2
- LRP1B | c.1408G>T p.V470F | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV101259487; called by muse, mutect2
- LRP2 | c.11953G>C p.G3985R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99789803; called by muse, mutect2
- LRRC7 | c.1432G>T p.D478Y (on ENST00000651989 / NM_001370785.2; = p.D445Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99228088, COSV99228937; called by muse, mutect2, varscan2
- LSG1 | c.1570G>T p.G524* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99503461; called by muse, mutect2, varscan2
- LY9 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as COSV99627289; called by muse, mutect2
- MADD | c.4226A>T p.Y1409F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100211863; called by muse, mutect2
- MAGEB2 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as COSV100975737; called by muse, mutect2
- MANEA | c.401G>T p.R134I | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100721625; called by muse, mutect2, varscan2
- MAP2 | c.4072G>T p.E1358* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as COSV52292570; called by muse, mutect2
- MARCHF1 | c.229C>G p.Q77E (on ENST00000274056; = p.Q60E on NM_017923.4) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV56818881, COSV99922290; called by muse, mutect2, varscan2
- MARCO | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59051526; called by muse, mutect2
- MARK1 | c.1802G>T p.R601L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV100857474, COSV65065258; called by muse, mutect2, varscan2
- MBD1 | c.1697G>A p.G566E (on ENST00000269468 / NM_001323950.1; = p.G464E on NM_002384.2) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99496994; called by muse, mutect2
- MBD3L1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV99978028; called by muse, mutect2, varscan2
- MBD3L1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV99978029; called by muse, mutect2, varscan2
- MC3R | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV54765170, COSV99710792; called by muse, mutect2
- MCOLN3 | c.1358C>A p.S453Y | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100352919; called by muse, mutect2, varscan2
- MDC1 | c.5563G>T p.D1855Y | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV100902994, COSV100903029; called by muse, mutect2
- MEDAG | c.644T>A p.V215E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100995311; called by muse, mutect2, varscan2
- MEGF10 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV99175372; called by muse, mutect2, varscan2
- MEMO1 | c.572G>T p.C191F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99704551; called by muse, mutect2
- MLLT3 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); catalogued as rs1262896985, COSV100581457, COSV63502436; called by muse, mutect2, varscan2
- MMP16 | c.709+1G>T p.X237_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | catalogued as COSV54195718; called by muse, mutect2, varscan2
- MMS22L | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs770628837, COSV99247560; called by muse, mutect2, varscan2
- MON1B | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.503); catalogued as COSV99941822; called by muse, mutect2, varscan2
- MPO | c.926G>T p.C309F | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99832941; called by muse, mutect2
- MPP2 | c.1156G>T p.G386* (on ENST00000461854 / NM_001278372.2; = p.G362* on NM_005374.5) | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99290703; called by muse, mutect2, varscan2
- MRGPRX4 | c.517T>C p.C173R | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100049815; called by muse, mutect2
- MROH7 | c.1937G>T p.R646L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.203); catalogued as COSV100273889; called by muse, mutect2, varscan2
- MTCL1 | c.1800G>T p.E600D (on ENST00000306329 / NM_001378206.1; = p.E240D on NM_015210.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.955); catalogued as rs771327068, COSV100095365; called by muse, mutect2
- MTUS2 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV101462332, COSV70917812; called by muse, mutect2, varscan2
- MUC15 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV99846609; called by muse, mutect2, varscan2
- MUC16 | c.32369C>T p.S10790L | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.351); catalogued as COSV101197798, COSV67480339; called by muse, mutect2
- MUC16 | c.8810C>A p.P2937Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.181); catalogued as COSV67460877; called by muse, mutect2, varscan2
- MYCBP2 | c.1674A>T p.L558F (on ENST00000357337; = p.L596F on NM_015057.5) | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.831); catalogued as COSV100631383; called by muse, mutect2
- MYO18B | c.4090C>A p.L1364M | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.728); catalogued as COSV100124689; called by muse, mutect2
- NAV2 | c.5113G>A p.E1705K (on ENST00000396087 / NM_001244963.2; = p.E1649K on NM_145117.5) | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100217508; called by muse, mutect2
- NAV2 | c.5911C>G p.Q1971E (on ENST00000396087 / NM_001244963.2; = p.Q1912E on NM_145117.5) | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); catalogued as COSV100217510; called by muse, mutect2
- NCKAP5 | c.4953G>C p.Q1651H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV100493856; called by muse, mutect2, varscan2
- NCOR2 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV100657748; called by muse, mutect2
- NF1 | c.4578-1G>A p.X1526_splice (on ENST00000358273 / NM_001042492.3; = p.X1505_splice on NM_000267.3) | Splice Site (SNP) | VAF 5/61 reads (8%) | catalogued as CS040851, COSV62226682; called by muse, mutect2
- NFAT5 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100591083, COSV63027833; called by mutect2, varscan2
- NID1 | c.392C>A p.T131N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1473024511, COSV99938084; called by muse, mutect2, varscan2
- NLRP1 | c.3172T>C p.C1058R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99335151; called by muse, mutect2
- NLRP4 | c.1507C>G p.L503V | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.279); catalogued as COSV100016881; called by muse, mutect2
- NLRP8 | c.233C>A p.T78K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99405775; called by muse, mutect2, varscan2
- NLRP8 | c.1271C>A p.T424N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99405777; called by muse, mutect2, varscan2
- NOC4L | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs369215601; called by muse, mutect2, varscan2
- NPAP1 | c.2081C>A p.P694H | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100275912; called by muse, mutect2
- NPM2 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99235802; called by muse, mutect2, varscan2
- NRXN2 | c.3175C>T p.R1059W | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200881363, COSV55454740; called by mutect2, varscan2
- NYNRIN | c.1027G>T p.V343L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as rs1159240810, COSV101230667; called by muse, mutect2, varscan2
- OBSCN | c.23851C>T p.R7951C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100805135, COSV62426700; called by muse, mutect2, varscan2
- OPLAH | c.2793G>C p.Q931H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV101470856; called by muse, mutect2, varscan2
- OR10K1 | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); catalogued as rs892439639, COSV56873298, COSV99193859; called by muse, mutect2
- OR11H1 | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 12/257 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99421934; called by muse, mutect2
- OR13C5 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV101053152; called by muse, mutect2
- OR13C5 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV101053153, COSV66164640; called by muse, mutect2, varscan2
- OR14A16 | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs140410550, COSV62927592; called by muse, mutect2, varscan2
- OR2G2 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100189897, COSV60741630; called by muse, mutect2, varscan2
- OR2G3 | c.360G>T p.L120F | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.114); catalogued as COSV100180706; called by muse, mutect2, varscan2
- OR2V2 | c.274T>C p.S92P | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV100080212; called by muse, mutect2
- OR4A15 | c.684G>T p.L228F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.03); catalogued as rs756115731, COSV100124304, COSV59038052; called by muse, varscan2
- OR4C16 | c.821C>A p.T274K | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100114218; called by muse, mutect2
- OR4C6 | c.647A>G p.Y216C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs747527406, COSV58602519, COSV58603124; called by muse, mutect2, varscan2
- OR4L1 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as rs1386093428, COSV100235854, COSV59848845; called by muse, mutect2, varscan2
- OR4N5 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100374185; called by muse, mutect2
- OR4S2 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100412746; called by muse, mutect2
- OR5AR1 | c.152C>A p.T51K | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV100265746; called by muse, mutect2
- OR5D13 | c.370C>A p.R124S | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100686791; called by muse, mutect2, varscan2
- OR5P2 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV100271334, COSV100271422; called by muse, mutect2, varscan2
- OR5V1 | c.227G>T p.S76I | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101011414; called by muse, mutect2
- OR6S1 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100289481; called by muse, mutect2, varscan2
- OR7G1 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV99528740; called by muse, mutect2, varscan2
- OR8G1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58383271; called by muse, mutect2, varscan2
- OR8H2 | c.919A>G p.R307G | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV100542441; called by muse, mutect2
- OR8I2 | c.26T>A p.V9D | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100136222; called by muse, mutect2
- OR8K3 | c.681G>T p.R227S | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV100449876; called by muse, mutect2
- OTOP3 | c.788C>G p.T263S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.249); catalogued as COSV100172994; called by muse, mutect2, varscan2
- P2RY12 | c.636T>G p.I212M | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99854290; called by muse, mutect2
- PAN2 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs866417046, COSV99228444; called by muse, mutect2, varscan2
- PAPPA2 | c.1843C>A p.Q615K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100867005; called by muse, mutect2, varscan2
- PAQR5 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100575590; called by muse, mutect2, varscan2
- PBX3 | c.818A>G p.K273R | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100655556; called by muse, mutect2, varscan2
- PCDH11Y | c.228G>T p.L76F (on ENST00000400457 / NM_032973.2; = p.L65F on NM_032971.3) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV99292391; called by muse, mutect2, varscan2
- PCDH18 | c.2520G>T p.Q840H | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV100787457; called by muse, mutect2
- PCDHA12 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1158750138, COSV56550425; called by muse, mutect2
- PCDHA5 | c.1558C>A p.Q520K | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV100972484; called by muse, mutect2, varscan2
- PCDHB10 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV53376097, COSV99504820; called by muse, mutect2, varscan2
- PCDHB5 | c.2033C>A p.A678D | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.001); catalogued as rs781831543, COSV99169347; called by muse, mutect2, varscan2
- PCDHB6 | c.1307C>A p.T436N | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV50707956, COSV99170704; called by muse, mutect2, varscan2
- PCNP | c.491G>C p.R164P | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99504140; called by muse, mutect2, varscan2
- PDE1C | c.1596G>C p.K532N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs768945874, COSV100373466; called by muse, mutect2, varscan2
- PDGFRL | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99286598; called by muse, mutect2, varscan2
- PDZD2 | c.7679C>G p.T2560R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV56850866, COSV99226216; called by muse, mutect2, varscan2
- PDZRN3 | c.2964G>T p.Q988H | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV99731441; called by muse, mutect2
- PEX5L | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as rs150624644; called by muse, mutect2, varscan2
- PGPEP1L | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as COSV99158470; called by muse, mutect2
- PKHD1L1 | c.383A>T p.K128I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV101006666; called by muse, mutect2, varscan2
- PLA2G4A | c.776T>A p.V259D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100820663; called by muse, mutect2
- PLA2G4A | c.2180C>G p.S727C | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV66554408; called by muse, mutect2
- PLCZ1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV99856757; called by muse, mutect2, varscan2
- PLEKHA5 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV100164592; called by muse, mutect2
- PLEKHA7 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV100850375; called by muse, mutect2
- PLEKHH1 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100233414; called by muse, varscan2
- PLPP3 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV100984776; called by muse, mutect2
- PNMA8B | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100885501; called by muse, mutect2
- PNPLA6 | c.3386G>T p.G1129V (on ENST00000414982 / NM_001166111.2; = p.G1081V on NM_006702.5) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555751016, COSV99654281; called by muse, mutect2, varscan2
- POM121L12 | c.821C>A p.S274Y | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV101374961, COSV68692749; called by muse, mutect2, varscan2
- POPDC3 | c.166T>A p.L56M | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV99633965; called by muse, mutect2, varscan2
- POU2F1 | c.1316C>T p.P439L (on ENST00000541643 / NM_001365848.1; = p.P462L on NM_002697.4) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1210096722, COSV99611833; called by muse, mutect2, varscan2
- PPFIA3 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV61954524; called by muse, mutect2
- PPP1R3A | c.2677G>T p.D893Y | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99491891, COSV99493393; called by muse, mutect2
- PPP6C | c.261C>G p.Y87* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as COSV101001228; called by muse, mutect2, varscan2
- PRKD1 | c.877G>T p.G293W | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100121301; called by muse, mutect2, varscan2
- PRKRIP1 | c.457G>T p.G153* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100700353; called by mutect2, varscan2
- PRLR | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV99184689; called by muse, mutect2, varscan2
- PRR27 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV100748884; called by muse, mutect2, varscan2
- PSEN2 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs567036599, COSV100423241; called by mutect2, varscan2
- PTPRD | c.5187del p.W1729Cfs*11 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as COSV61975163; called by mutect2, pindel*
- QRICH2 | c.1876G>T p.V626L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1388590927, COSV99429569; called by muse, mutect2, varscan2
- QSER1 | c.2411C>T p.P804L (on ENST00000399302; = p.P933L on NM_001076786.3) | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV101234944; called by muse, mutect2
- RADX | c.1769G>T p.R590I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100998901; called by muse, mutect2, varscan2
- RAPGEF4 | c.2206A>G p.I736V | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99911332; called by muse, mutect2, varscan2
- RASAL2 | c.971G>T p.S324I | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100862803; called by muse, mutect2
- RB1CC1 | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99212603; called by muse, mutect2
- RCOR1 | c.740A>G p.D247G | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99217734; called by muse, mutect2, varscan2
- RFPL2 | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375435988; called by muse, mutect2, varscan2
- RICTOR | c.3329G>T p.R1110L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs766067681, COSV57122360, COSV99705554; called by muse, mutect2, varscan2
- RNF112 | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.474); catalogued as COSV101518358; called by muse, mutect2
- ROS1 | c.4669+1G>T p.X1557_splice | Splice Site (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100877570; called by muse, mutect2, varscan2
- RP1 | c.1593A>T p.L531F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV99608461; called by mutect2, varscan2
- RPL7A | c.692A>C p.D231A | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV100034807; called by muse, mutect2
- RRM1 | c.625G>C p.G209R | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100331425; called by muse, mutect2
- RSBN1L | c.1865G>T p.R622L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100616190, COSV58507666; called by muse, mutect2
- RTN4RL1 | c.328A>G p.N110D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100486739; called by muse, mutect2, varscan2
- RUBCN | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754358548, COSV56364971; called by muse, mutect2, varscan2
- RYR2 | c.7901C>T p.S2634L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100772171; called by muse, mutect2, varscan2
- SARS1 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as rs1167910316, COSV99321495; called by muse, mutect2, varscan2
- SCG3 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99591132; called by muse, mutect2, varscan2
- SCN7A | c.3317G>T p.R1106L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs201204940, COSV101313330; called by muse, mutect2, varscan2
- SEMA3A | c.2201G>T p.R734L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99547660; called by muse, varscan2
- SEMA3D | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV52402889, COSV99406191; called by muse, mutect2
- SEMA5A | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); catalogued as COSV101228630; called by muse, mutect2, varscan2
- SERPINB11 | c.1046C>A p.A349D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101236301; called by muse, mutect2, varscan2
- SF3B1 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100135470, COSV59215581; called by muse, mutect2, varscan2
- SGIP1 | c.171+2T>A p.X57_splice | Splice Site (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99392502; called by muse, mutect2
- SH3PXD2A | c.1669G>C p.E557Q (on ENST00000369774 / NM_001365079.1; = p.E529Q on NM_014631.2) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100280384; called by muse, mutect2
- SI | c.3362C>A p.A1121E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as COSV100016723; called by muse, mutect2, varscan2
- SIGLEC14 | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99707805; called by muse, mutect2
- SIMC1 | c.1351A>G p.I451V (on ENST00000443967 / NM_001308196.1; = p.I470V on NM_001308195.2) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.024); catalogued as COSV100365845; called by muse, mutect2
- SKIDA1 | c.2169G>C p.E723D | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV101481334; called by muse, mutect2
- SLA | c.710T>A p.L237Q (on ENST00000338087 / NM_001045556.3; = p.L277Q on NM_006748.4) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99602556; called by muse, mutect2
- SLC16A13 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV100338727; called by muse, mutect2, varscan2
- SLC16A9 | c.715A>T p.R239W | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV101264452; called by muse, mutect2
- SLC1A6 | c.787G>C p.A263P | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV55668974, COSV99694090; called by mutect2, varscan2
- SLC25A31 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | catalogued as COSV55418127, COSV99829573; called by muse, mutect2
- SLC25A53 | c.534C>G p.F178L | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.306); catalogued as COSV100656104; called by muse, mutect2
- SLC26A3 | c.1735C>T p.R579* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as rs1171640656, CM115697, COSV60642015; called by muse, mutect2, varscan2
- SLC36A2 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100079351; called by muse, mutect2
- SLC44A5 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100902405; called by muse, mutect2, varscan2
- SLC4A10 | c.1826T>G p.V609G (on ENST00000446997 / NM_001354461.2; = p.V579G on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99765273; called by muse, mutect2, varscan2
- SLC4A5 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100697921; called by muse, mutect2, varscan2
- SLC5A3 | c.2117G>T p.C706F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1166111105, COSV100758031; called by muse, mutect2, varscan2
- SLC8A1 | c.668C>A p.S223Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100247090; called by muse, mutect2, varscan2
- SLITRK4 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV62023314; called by muse, mutect2, varscan2
- SLITRK6 | c.713C>A p.P238Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.153); catalogued as COSV101233274; called by muse, mutect2
- SLITRK6 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101233275; called by muse, mutect2, varscan2
- SNTG1 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs867068094, COSV52461875, COSV99385396; called by muse, mutect2, varscan2
- SNX5 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376255348; called by muse, mutect2, varscan2
- SPATA16 | c.1533C>A p.D511E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765712332, COSV100651510; called by muse, mutect2, varscan2
- SPATA31D1 | c.4352C>A p.A1451E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.224); catalogued as COSV100782992; called by muse, mutect2, varscan2
- SPEF2 | c.3212T>G p.L1071R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100608550; called by muse, mutect2
- SPTA1 | c.5692G>A p.E1898K | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV63758463, COSV63762100; called by muse, mutect2, varscan2
- SPTA1 | c.3056C>A p.A1019D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.315); catalogued as COSV100935388; called by muse, mutect2
- SREBF1 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV99889350; called by muse, mutect2
- STIL | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99681236; called by muse, mutect2, varscan2
- STON2 | c.767A>G p.D256G (on ENST00000649389 / NM_001366849.2; = p.D199G on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as COSV99965057; called by muse, mutect2
- SULF1 | c.885+1G>T p.X295_splice | Splice Site (SNP) | VAF 7/76 reads (9%) | catalogued as rs1470452524, COSV52674040, COSV99483980; called by muse, mutect2, varscan2
- SVEP1 | c.4389G>T p.M1463I | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100236799, COSV100238802; called by muse, mutect2
- SVEP1 | c.4388T>A p.M1463K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100238803; called by muse, mutect2
- SWT1 | c.1364A>G p.D455G | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.433); catalogued as rs1470673561, COSV100833480; called by muse, mutect2, varscan2
- SYNE1 | c.8805C>G p.D2935E (on ENST00000367255 / NM_182961.4; = p.D2942E on NM_033071.3) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV99574938; called by muse, mutect2, varscan2
- TAF1 | c.1177G>T p.D393Y (on ENST00000373790 / NM_138923.4; = p.D414Y on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99336654, COSV99336764; called by muse, mutect2
- TAS1R2 | c.456C>A p.N152K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV100946316; called by muse, mutect2
- TAS2R30 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV101115356; called by muse, mutect2, varscan2
- TBC1D32 | c.2028G>T p.W676C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1373949539; called by muse, mutect2
- TBL1X | c.152A>T p.K51M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV99483030; called by muse, mutect2
- TBX20 | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.03); catalogued as rs760317856, COSV101282406; called by muse, mutect2, varscan2
- TCF7L2 | c.632T>C p.F211S (on ENST00000355995 / NM_001367943.1; = p.F188S on NM_030756.5) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99526489; called by muse, mutect2, varscan2
- TCP11 | c.37C>A p.P13T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs1381928600, COSV55132891; called by muse, mutect2
- TENM1 | c.1877-1G>A p.X626_splice | Splice Site (SNP) | VAF 7/74 reads (9%) | catalogued as COSV100950570; called by muse, mutect2
- TFAP2D | c.468G>T p.M156I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99146865; called by muse, mutect2, varscan2
- TFCP2L1 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.588); catalogued as COSV99748612; called by muse, mutect2
- TLE4 | c.1292G>T p.R431L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54630968, COSV99512855; called by muse, mutect2
- TLL1 | c.1346G>C p.W449S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as COSV99288597; called by muse, mutect2, varscan2
- TLL2 | c.1825C>G p.L609V | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100780429; called by muse, mutect2
- TLR4 | c.338C>A p.P113H (on ENST00000355622 / NM_138554.5; = p.P73H on NM_003266.4) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100790682; called by muse, mutect2
- TMEM196 | c.224G>C p.C75S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV101337515; called by muse, mutect2
- TMEM248 | c.383G>C p.G128A | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.218); catalogued as COSV100447449, COSV58577462; called by mutect2, varscan2
- TMEM255A | c.932C>A p.S311Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100434296, COSV58533045; called by muse, mutect2, varscan2
- TMEM71 | c.430G>T p.E144* (on ENST00000523829 / NM_001382398.1; = p.E125* on NM_144649.3) | Nonsense Mutation (SNP) | VAF 7/80 reads (9%) | catalogued as COSV100785675; called by muse, mutect2
- TMX3 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 5/121 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV100218393, COSV100218517; called by muse, mutect2
- TNFAIP3 | c.1987G>C p.G663R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52799382, COSV99397142; called by mutect2, varscan2
- TNN | c.3200C>T p.P1067L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99512710; called by muse, mutect2
- TPR | c.6946A>G p.S2316G | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100798291; called by muse, mutect2
- TRIM72 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100265460; called by muse, mutect2, varscan2
- TRIO | c.950G>T p.R317L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as COSV100710793; called by muse, mutect2, varscan2
- TRIP6 | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99308087; called by muse, mutect2, varscan2
- TRPA1 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV100084904; called by muse, mutect2
- TTN | c.58827C>A p.N19609K (on ENST00000591111; = p.N12185K on NM_003319.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | PolyPhen probably damaging (0.997); catalogued as COSV100624805; called by mutect2, varscan2
- TTN | c.41794G>C p.A13932P (on ENST00000591111; = p.A6508P on NM_003319.4) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | PolyPhen benign (0.084); catalogued as COSV100624808; called by muse, mutect2, varscan2
- UBE2H | c.161G>T p.R54I | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100842530; called by muse, mutect2
- UBE2O | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.054); catalogued as COSV100084914; called by muse, mutect2
- UGT2B4 | c.1156C>A p.H386N | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100522575; called by muse, mutect2
- UNC5C | c.1364C>A p.A455D | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs759021473, COSV101498000; called by muse, mutect2
- UNC79 | c.2875A>T p.I959F (on ENST00000393151 / NM_001346218.2; = p.I782F on NM_020818.5) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.471); catalogued as COSV56411964, COSV99829419; called by muse, mutect2, varscan2
- USH2A | c.14152G>T p.A4718S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs1038432544, COSV100240294; called by muse, mutect2, varscan2
- USH2A | c.6974T>A p.L2325Q | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV100240298; called by muse, mutect2, varscan2
- USP38 | c.437G>C p.R146P | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV100189423; called by muse, mutect2
- USP48 | c.524A>T p.D175V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100380175; called by muse, mutect2
- USP6 | c.3865C>A p.Q1289K | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated, low confidence (0.62); PolyPhen possibly damaging (0.681); catalogued as COSV100004686; called by muse, mutect2
- USP9X | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV100199926; called by muse, mutect2
- UVRAG | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100638554; called by muse, mutect2, varscan2
- VPS13B | c.11647G>C p.E3883Q | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs910829293, COSV100663065; called by muse, mutect2
- VXN | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.084); catalogued as COSV100560114; called by muse, mutect2
- WDR72 | c.2861G>T p.C954F | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100854952; called by muse, mutect2
- ZBTB10 | c.1071G>C p.Q357H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100990281; called by muse, mutect2, varscan2
- ZCWPW1 | c.1878del p.Q627Rfs*? | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | catalogued as COSV52202246; called by mutect2, pindel
- ZFHX4 | c.774C>A p.N258K | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1178807555; called by muse, mutect2
- ZGRF1 | c.5545G>T p.A1849S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.065); catalogued as COSV101500650; called by muse, mutect2, varscan2
- ZIC1 | c.807C>A p.H269Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99292264; called by muse, mutect2, varscan2
- ZMAT3 | c.610A>T p.K204* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100265330; called by muse, mutect2, varscan2
- ZMPSTE24 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65638816; called by muse, mutect2
- ZMYM4 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV100110988; called by muse, mutect2, varscan2
- ZNF169 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100566341; called by muse, mutect2
- ZNF229 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV99350752; called by muse, mutect2, varscan2
- ZNF318 | c.5228C>T p.S1743F | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs1302743790, COSV100546432; called by muse, mutect2
- ZNF425 | c.396G>C p.E132D | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV100955574; called by muse, mutect2
- ZNF560 | c.1786G>T p.G596* | Nonsense Mutation (SNP) | VAF 13/94 reads (14%) | catalogued as rs1306438471, COSV100038910, COSV100039126; called by muse, mutect2, varscan2
- ZNF607 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs971470834, COSV100777941; called by muse, mutect2, varscan2
- ZNF683 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 3/35 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV100853732; called by muse, mutect2
- C10orf120 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.814); called by muse, mutect2
- DNM1L | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- DUS3L | c.772del p.E258Kfs*28 | Frame Shift Del (DEL) | VAF 3/19 reads (16%) | called by mutect2, pindel, varscan2
- GRM3 | c.2563C>A p.Q855K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- HIF1A | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- KCNA4 | c.1427G>T p.R476L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- LAMB1 | c.2886_2887delinsA p.Y962* | Nonsense Mutation (DEL) | VAF 7/85 reads (8%) | called by pindel, varscan2*
- MAGEB6B | c.161G>T p.R54M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MCF2L2 | c.68C>A p.T23N | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.709); called by muse, mutect2
- PAPPA2 | c.5263G>T p.G1755W | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAX4 | c.562+1del p.X188_splice | Splice Site (DEL) | VAF 9/80 reads (11%) | called by mutect2, pindel, varscan2
- PCDH11Y | c.4017del p.L1340Cfs*16 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- PDIA6 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.287); called by muse, mutect2
- PDILT | c.739A>T p.N247Y | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PLPPR4 | c.257del p.Y86Ffs*54 | Frame Shift Del (DEL) | VAF 16/126 reads (13%) | called by mutect2, varscan2
- POLD2 | c.280del p.V94Wfs*51 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- PPP1R3A | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- PRPF8 | c.2018C>G p.T673R | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PUF60 | c.1501G>A p.E501K (on ENST00000526683 / NM_001362896.2; = p.E484K on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- SERPINA1 | c.819del p.A274Pfs*50 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- SF3B2 | c.1854del p.M619Cfs*3 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel, varscan2
- SMC4 | c.1372A>G p.K458E | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SPATA31A1 | c.3403C>A p.P1135T | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- SPEF2 | c.5278del p.D1760Tfs*2 | Frame Shift Del (DEL) | VAF 13/145 reads (9%) | called by mutect2, pindel
- TRAJ42 | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- TRAV8-7 | c.337A>T p.R113W | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); called by mutect2, varscan2
- ABLIM3 | c.1575G>T p.L525= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- AHNAK2 | c.12141C>G p.L4047= | Silent (SNP) | VAF 11/267 reads (4%) | catalogued as COSV100315593; called by muse, mutect2
- AKAP6 | c.4200A>G p.P1400= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV99803421; called by muse, mutect2, varscan2
- ALG13 | c.2556A>T p.A852= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99322836; called by muse, mutect2, varscan2
- ANKRD55 | c.1443T>C p.N481= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV100591543; called by muse, mutect2, varscan2
- AP002512.3 | c.1110C>A p.S370= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99688087; called by muse, mutect2
- APOL2 | c.168G>C p.L56= | Silent (SNP) | VAF 9/161 reads (6%) | catalogued as COSV50772457, COSV50772473; called by muse, mutect2
- ASTN2 | c.651G>C p.L217= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100529590; called by muse, varscan2
- AZU1 | c.675C>A p.G225= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs775497156, COSV99297408; called by muse, mutect2, varscan2
- BRI3 | c.195C>T p.T65= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs768418013, COSV99805603; called by muse, mutect2, varscan2
- CACNA1E | c.4390A>C p.R1464= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100704543; called by muse, mutect2, varscan2
- CACNA1E | c.4767G>A p.Q1589= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV62411996; called by muse, mutect2
- CADPS | c.1956C>T p.I652= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV99340223, COSV99341496; called by muse, mutect2
- CDC40 | c.426A>G p.S142= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs780304121, COSV100309521; called by muse, mutect2, varscan2
- CECR2 | c.4062T>C p.S1354= (on ENST00000342247 / NM_001290047.2; = p.S1170= on NM_001290046.1) | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs570641867, COSV99378815; called by muse, mutect2, varscan2
- CER1 | c.633T>A p.P211= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV101097911; called by muse, mutect2, varscan2
- CFH | c.1533C>T p.I511= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100809983, COSV66410847; called by muse, mutect2
- CHD5 | c.2226C>T p.L742= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99314608; called by muse, mutect2
- CIT | c.732G>T p.A244= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs747648400, COSV99950590; called by muse, mutect2, varscan2
- CLCA1 | c.507C>T p.Y169= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV99322705; called by muse, mutect2
- CLEC4A | c.57A>T p.S19= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99983745; called by muse, mutect2, varscan2
- CSH1 | c.636G>A p.E212= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100298183, COSV100298414; called by muse, mutect2, varscan2
- CYP11B1 | c.6A>C p.A2= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV99455542; called by muse, mutect2
- DCTN1 | c.2352C>T p.L784= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100721034; called by muse, mutect2, varscan2
- DDX24 | c.1581G>A p.K527= | Silent (SNP) | VAF 5/111 reads (5%) | catalogued as rs764285197, COSV104400645; called by muse, mutect2
- DKK3 | c.333G>T p.V111= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100485085; called by muse, mutect2
- DLL3 | c.9C>T p.S3= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV99219349; called by muse, mutect2, varscan2
- DMBT1 | c.6609C>T p.S2203= (on ENST00000338354 / NM_001377530.1; = p.S1446= on NM_004406.3) | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs768047546, COSV57564453; called by muse, mutect2, varscan2
- DOCK2 | c.5025G>T p.T1675= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV99914476; called by muse, mutect2, varscan2
- EVI5 | c.1983G>T p.V661= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV100945459; called by muse, mutect2, varscan2
- FAM135B | c.3336G>T p.L1112= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99426402; called by muse, mutect2, varscan2
- FHOD3 | c.1063C>A p.R355= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV57173045, COSV99942301; called by muse, mutect2
- FIGN | c.186G>T p.L62= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV100292799; called by muse, mutect2
- FLNA | c.3255C>T p.P1085= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs782231907, COSV100775029; ClinVar: likely benign; called by muse, mutect2
- FSTL5 | c.936C>T p.T312= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV100059627; called by muse, mutect2, varscan2
- FZD10 | c.1545G>A p.G515= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99969560; called by muse, mutect2, varscan2
- GABRG1 | c.225T>C p.Y75= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV99778553; called by muse, mutect2
- GABRR2 | c.1077G>T p.L359= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV101299017; called by muse, mutect2
- GCC1 | c.255C>T p.D85= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs751381399, COSV99133883; called by mutect2, varscan2
- GRIA2 | c.1152G>A p.R384= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV99645550; called by muse, mutect2
- HIVEP2 | c.1584G>A p.P528= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs375645482; called by muse, mutect2, varscan2
- HNF4G | c.154C>A p.R52= (on ENST00000354370 / NM_001330561.2; = p.R99= on NM_004133.5) | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100584860, COSV100584883; called by muse, mutect2, varscan2
- HOXB3 | c.789C>T p.G263= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV57488626; called by muse, mutect2, varscan2
- IGHV2-5 | c.108C>A p.T36= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- IGHV3-53 | c.345G>C p.A115= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as rs1555544951; called by muse, mutect2, varscan2
- IL32 | c.603G>C p.L201= (on ENST00000396890 / NM_001308078.4; = p.L155= on NM_004221.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99145552; called by muse, mutect2, varscan2
- ITK | c.72G>T p.S24= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV101439853, COSV70060975; called by muse, mutect2, varscan2
- KDM5A | c.2064C>G p.L688= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV101239026; called by muse, mutect2, varscan2
- KLK9 | c.354C>T p.P118= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99144065; called by muse, mutect2, varscan2
- KRT74 | c.1062C>A p.T354= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV99977654; called by muse, mutect2
- KRTAP10-12 | c.321C>T p.P107= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as rs371482755, COSV59967119; called by muse, mutect2, varscan2
- LARP6 | c.759G>T p.V253= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100150996; called by muse, mutect2
- LDHD | c.972C>G p.L324= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100097433; called by muse, mutect2
- LHX8 | c.951C>A p.P317= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV99634218; called by muse, mutect2, varscan2
- LRCH3 | c.939C>T p.F313= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs1252060671, COSV100605210; called by muse, mutect2, varscan2
- MAN1A2 | c.615C>T p.L205= | Silent (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- MEGF10 | c.999C>T p.Y333= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV57247610; called by muse, mutect2, varscan2
- MOXD1 | c.1383G>A p.R461= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- MRPL17 | c.337C>A p.R113= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV99996907; called by muse, mutect2
- MRPS25 | c.306C>T p.I102= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV99507810; called by muse, mutect2
- MS4A14 | c.1269T>C p.H423= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100280666; called by muse, mutect2
- MUC16 | c.30768A>G p.T10256= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV101200723, COSV101200857; called by muse, mutect2, varscan2
- MUC5B | c.5973C>A p.T1991= | Silent (SNP) | VAF 19/203 reads (9%) | catalogued as rs761679796; called by muse, mutect2, varscan2
- NAT2 | c.588T>A p.P196= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99674171; called by muse, mutect2, varscan2
- NLRP12 | c.1191C>T p.L397= | Silent (SNP) | VAF 40/194 reads (21%) | catalogued as COSV60751270; called by muse, mutect2, varscan2
- NMI | c.585C>T p.D195= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99693494; called by muse, mutect2
- NOBOX | c.723C>A p.P241= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99779623; called by muse, mutect2, varscan2
- NOS1 | c.687C>A p.A229= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100501192; called by muse, mutect2, varscan2
- NOTCH1 | c.5544G>A p.L1848= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99490651; called by muse, mutect2
- NSUN2 | c.2301G>A p.R767= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV52954501; called by mutect2, varscan2
- OR10K1 | c.591G>T p.L197= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV56870814, COSV99193857; called by muse, mutect2
- OR10S1 | c.735C>A p.A245= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV73342676; called by muse, mutect2, varscan2
- OR1J4 | c.94T>C p.L32= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs1564185874, COSV61590283; called by muse, mutect2, varscan2
- OR2J2 | c.933G>T p.G311= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV101013431; called by muse, mutect2
- OR2M5 | c.642C>A p.I214= | Silent (SNP) | VAF 17/287 reads (6%) | catalogued as COSV100822853; called by muse, mutect2
- OR2T3 | c.906C>A p.V302= | Silent (SNP) | VAF 11/174 reads (6%) | called by muse, mutect2
- OR4A15 | c.912A>C p.V304= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV59036920; called by muse, mutect2, varscan2
- OR4C13 | c.450C>A p.G150= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV101634218; called by muse, mutect2
- OR4C3 | c.105C>A p.V35= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100168189, COSV60587812; called by muse, mutect2
- OR5R1 | c.738G>T p.V246= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100393544; called by mutect2, varscan2
- ORMDL3 | c.45G>A p.R15= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs139405150; called by muse, mutect2, varscan2
- PC | c.1131G>T p.R377= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs1387922807, COSV100852319; called by mutect2, varscan2
- PCDHB3 | c.513T>A p.T171= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV99166250; called by muse, mutect2, varscan2
- PEX3 | c.1062G>T p.V354= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100852230; called by muse, varscan2
- PGAP4 | c.1038G>T p.R346= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100877865, COSV66388505; called by muse, mutect2, varscan2
- PIK3R4 | c.3126A>T p.G1042= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100768556; called by muse, mutect2
- POP1 | c.2772A>T p.G924= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100856046; called by muse, mutect2, varscan2
- PTK2B | c.2625G>T p.R875= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100594304; called by muse, mutect2
- RADX | c.78G>A p.R26= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100998900; called by muse, mutect2, varscan2
- RALGAPB | c.2916C>T p.P972= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99485610; called by muse, mutect2
- RHBG | c.468C>A p.A156= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99659961; called by muse, mutect2
- ROPN1L | c.237G>A p.L79= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99928752; called by muse, mutect2
- RSPH4A | c.96C>T p.P32= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV99994263; called by muse, mutect2
- RYR2 | c.1249C>A p.R417= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs564822776, COSV63667785; called by muse, mutect2, varscan2
- RYR3 | c.7263C>A p.L2421= (on ENST00000389232; = p.L2422= on NM_001036.6) | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs763965297, COSV101213771; called by muse, mutect2, varscan2
- SERPINB7 | c.1017C>A p.A339= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100320986; called by muse, mutect2, varscan2
- SLC41A1 | c.21G>A p.P7= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs765974634, COSV65651119; called by muse, mutect2, varscan2
- SLC5A3 | c.342C>G p.S114= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as COSV100758030, COSV62970490; called by muse, mutect2, varscan2
- SPG11 | c.3360A>G p.L1120= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV99969307; called by muse, mutect2
- STAG2 | c.2697C>T p.I899= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV99494904; called by muse, mutect2
- SUGP1 | c.96C>T p.I32= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99448987; called by muse, mutect2, varscan2
- TAAR8 | c.588C>A p.G196= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV51586762, COSV99257301; called by muse, mutect2
- TENM1 | c.1809C>A p.G603= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100950572; called by muse, varscan2
- TNFRSF21 | c.684C>T p.A228= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99730099; called by muse, mutect2
- TPP1 | c.933C>T p.L311= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV54994235; called by muse, mutect2
- TRAFD1 | c.1098C>A p.I366= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- TRIM26 | c.849C>T p.T283= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs573237830, COSV101443963; called by muse, mutect2
- TTN | c.71169G>C p.L23723= (on ENST00000591111; = p.L16299= on NM_003319.4) | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100624801; called by muse, mutect2, varscan2
- TTN | c.10821A>T p.A3607= (on ENST00000591111; = p.A3561= on NM_003319.4) | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV100624811; called by muse, mutect2
- TYRO3 | c.1539C>A p.I513= | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as COSV99777981; called by muse, mutect2
- ULK1 | c.1116G>T p.A372= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100417165, COSV58854885; called by mutect2, varscan2
- VCAN | c.1896G>T p.T632= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV99426897; called by muse, mutect2, varscan2
- WSCD2 | c.273C>A p.P91= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV54592184; called by muse, mutect2, varscan2
- ZNF205 | c.1488C>T p.R496= | Silent (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- ZNF638 | c.1218A>G p.R406= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV100039593; called by muse, mutect2, varscan2
- AC017104.4 | chr2:231509196 C>G | 5'Flank (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- ACSM1 | c.1197+144G>T | Intron (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- ADGRA1 | chr10:133084962 G>T | 5'Flank (SNP) | VAF 9/125 reads (7%) | catalogued as rs968949444, COSV100811035; called by muse, mutect2
- ARHGEF25 | chr12:57620448 C>A | 3'Flank (SNP) | VAF 26/218 reads (12%) | catalogued as COSV99678225; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2575A>T | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100154081; called by muse, mutect2
- CPLANE1 | c.*2790C>T | 3'UTR (SNP) | VAF 6/41 reads (15%) | catalogued as rs1368362219, COSV99951395; called by muse, mutect2, varscan2
- CREB5 | c.465-32603C>T | Intron (SNP) | VAF 6/144 reads (4%) | catalogued as COSV100743818, COSV63225757; called by muse, mutect2
- CTSF | c.*2G>T | 3'UTR (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100074456; called by muse, mutect2
- CXCL17 | c.-1G>A | 5'UTR (SNP) | VAF 8/32 reads (25%) | catalogued as rs149050070; called by muse, mutect2
- DCHS2 | n.6488G>T | RNA (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100602381; called by muse, mutect2, varscan2
- MIR376A1 | n.52G>T | RNA (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- PLCB1 | c.3423+11842C>T | Intron (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100571833; called by muse, mutect2, varscan2
- SNORD115-25 | n.34G>A | RNA (SNP) | VAF 24/246 reads (10%) | called by muse, mutect2
- SNORD116-15 | n.64A>G | RNA (SNP) | VAF 24/226 reads (11%) | catalogued as rs756570845; called by muse, mutect2
- TMSB4X | c.*1T>C | 3'UTR (SNP) | VAF 14/64 reads (22%) | catalogued as COSV101020362; called by muse, mutect2, varscan2
- TUBB7P | n.1165A>G | RNA (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- VKORC1 | c.173+263G>A | Intron (SNP) | VAF 14/201 reads (7%) | catalogued as COSV100161830; called by muse, mutect2
- VN1R10P | n.409C>G | RNA (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
